Gene-level copy-number profile of tumor specimen TCGA-CC-5259-01A from TCGA case TCGA-CC-5259, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.1 years (21,946 days).
Specimen TCGA-CC-5259-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c39b182d-9cde-4d8a-a75b-251b04970578.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-5259-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate.
https://portal.gdc.cancer.gov/files/628b2d65-3bba-4e2a-9329-1a16a3794f2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,539; copy number 2: 35,024; copy number 3: 13,254; copy number 4: 1,579; copy number 5: 1,419.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,419 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,704,600–68,712,498, 1 gene, copy number 5: AC147055.1.
- chr19:22,902,538–23,147,221, 12 genes, copy number 5: AC022145.1, AC022145.2, ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1.
- chr19:36,259,540–58,605,223, 1,406 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
